Surgical pathology report (de-identified scan), TCGA case TCGA-R8-A6MO, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MD Anderson, specimen TCGA-R8-A6MO-01A (Primary Tumor).

[page 1 of 2]
(157.0cm 53.3kg BSA: 1.52m²)

Accession:
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) POSTERIOR PART RIGHT FRONTAL BRAIN TUMOR -
OLIGODENDROGLIOMA, GRADE II (WHO).
- (B) ANTERIOR PORTION RIGHT FRONTAL BRAIN
OLIGODENDROGLIOMA, GRADE II (WHO).
- (C) CINGULATE GYRUS, RIGHT FRONTAL LOBE -
OLIGODENDROGLIOMA, GRADE II (WHO). See comment.

CCF ICD-O-3
Oligodendroglioma, grade II
9450/3
Oligodendroglioma No S
9450/3
Site R Brain, supratentorial Nos
C71.0
Jt 7/5/13

COMMENT

The 1p/19q status of this tumor will be determined.

GROSS DESCRIPTION

(A) POSTERIOR PART RIGHT FRONTAL BRAIN TUMOR - Specimen consists of a single piece of cerebral cortex and underlying white matter which measures 7.5 x 6.5 x 3.0 cm. Representative portion submitted for frozen section and submitted in cassette A1 and additional representative sections are submitted in cassettes A2-A8.

*FS/DX: LOW-GRADE GLIOMA CONSISTENT WITH OLIGODENDROGLIOMA.

(B) ANTERIOR PORTION RIGHT FRONTAL BRAIN - A portion of brain including white and gray matter, measuring 3.5 x 2.5 x 1.8 cm. Serial sectioned and submitted in toto.

SECTION CODE: B1-B4, the entire specimen.

(C) CINGULATE GYRUS, RIGHT FRONTAL LOBE - A single piece of irregularly shaped white matter and gray matter. It measures 3.5 x 2.0 x 1.5 cm. A portion is submitted for frozen section and smear in cassette C1 and the remainder for permanent sections in cassettes C2-C5.

*FS/DX: INFILTRATING LOW-GRADE GLIOMA.

CLINICAL HISTORY

Oligodendroglioma, right frontal brain tumor.

SNOMED CODES

T-A2000, M-94503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 2]
Page: 2

F

(157.0cm 53.3kg BSA: 1.52m²

Accession

Specimen Date/Time:

ADDENDUM

Florescence in situ hybridization was performed for markers on chromosomes 1p and 19q and shows loss at both chromosomal arms. Combined 1p/19q loss has been shown to correlate with the oligodendroglial lineage and may predict a more favorable response to adjuvant therapy compared with tumors showing intact 1p/19q.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 0071b329-495f-4d24-ae55-2b4a3adea9b0 (TCGA-R8-A6MO.333C073F-08C4-475A-B622-6491FDA57205.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).